Somatic mutation profile of tumor specimen TCGA-55-7576-01A (aliquot TCGA-55-7576-01A-11D-2063-08) from TCGA case TCGA-55-7576, project TCGA-LUAD (Lung Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IB; Age at diagnosis: 54.5 years (19,917 days).
Specimen TCGA-55-7576-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 23323f4e-584a-42dd-b9c6-2ad74f2c9006.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-55-7576-10A (Blood Derived Normal), aliquot TCGA-55-7576-10A-01D-2063-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/e87a5ce4-3ac2-49db-80cd-1b0cec1a49bd

The open-access MAF lists 406 somatic variants for this specimen: 305 protein-altering or splice-affecting, 90 silent, 11 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 268, Silent 90, Nonsense Mutation 19, Frame Shift Del 8, Intron 5, Splice Site 4, RNA 4, Splice Region 4, 5'UTR 1, Translation Start Site 1, Frame Shift Ins 1, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.34G>A p.G12S | Missense Mutation (SNP) | VAF 21/33 reads (64%) | hotspot (GDC flag); SIFT deleterious (0.03); PolyPhen possibly damaging (0.582); catalogued as rs121913530, CM076251, COSV55497461, COSV55497469, COSV55497582, COSV56157736; ClinVar: not provided / pathogenic; called by muse, mutect2, varscan2
- TP53 | c.949C>T p.Q317* | Nonsense Mutation (SNP) | VAF 29/69 reads (42%) | hotspot (GDC flag); catalogued as rs764735889, COSV52685086, COSV53209009; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ABCA13 | c.10940C>T p.T3647I | Missense Mutation (SNP) | VAF 8/208 reads (4%) | SIFT deleterious (0); PolyPhen benign (0.029); catalogued as COSV101446769; called by muse, mutect2
- ABCC9 | c.3807G>T p.L1269F | Missense Mutation (SNP) | VAF 16/228 reads (7%) | SIFT deleterious (0.03); PolyPhen benign (0.119); catalogued as COSV99684482; called by muse, mutect2
- ABL1 | c.1747G>A p.G583S | Missense Mutation (SNP) | VAF 43/177 reads (24%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.001); catalogued as rs373147618, COSV59337769; called by muse, mutect2, varscan2
- ACOT7 | c.553G>T p.E185* (on ENST00000377855 / NM_181864.3; = p.E175* on NM_007274.4) | Nonsense Mutation (SNP) | VAF 5/43 reads (12%) | catalogued as COSV100830140; called by muse, mutect2, varscan2
- ACSF3 | c.136G>T p.V46L | Missense Mutation (SNP) | VAF 27/43 reads (63%) | SIFT deleterious (0.04); PolyPhen benign (0.019); catalogued as COSV100441095; called by muse, mutect2, varscan2
- ACTL7A | c.504G>T p.L168F | Missense Mutation (SNP) | VAF 22/93 reads (24%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV100453037; called by muse, mutect2, varscan2
- ADAMTSL3 | c.3964C>A p.P1322T | Missense Mutation (SNP) | VAF 79/182 reads (43%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV99716961; called by muse, mutect2, varscan2
- ADCY2 | c.3013C>A p.P1005T | Missense Mutation (SNP) | VAF 6/52 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99059534; called by muse, mutect2
- ADGRL3 | c.898G>T p.D300Y (on ENST00000506720 / NM_001322402.2; = p.D232Y on NM_015236.6) | Missense Mutation (SNP) | VAF 6/36 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV101546856, COSV101547263; called by muse, mutect2, varscan2
- ADORA3 | c.313G>A p.A105T | Missense Mutation (SNP) | VAF 8/48 reads (17%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.944); catalogued as rs746154553, COSV53987170; called by muse, mutect2, varscan2
- AHNAK2 | c.9730C>G p.P3244A | Missense Mutation (SNP) | VAF 69/211 reads (33%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs778879141, COSV100315597, COSV60911140, COSV60927542; called by muse, mutect2, varscan2
- AMH | c.1438C>T p.P480S | Missense Mutation (SNP) | VAF 9/34 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99677592; called by muse, mutect2, varscan2
- ANAPC5 | c.1129G>C p.A377P | Missense Mutation (SNP) | VAF 3/39 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV99945935; called by muse, mutect2
- APAF1 | c.2461A>G p.I821V (on ENST00000551964 / NM_181861.2; = p.I810V on NM_001160.3) | Missense Mutation (SNP) | VAF 12/55 reads (22%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV100452275; called by muse, mutect2, varscan2
- ARHGAP17 | c.2599C>G p.R867G (on ENST00000289968 / NM_001006634.3; = p.R789G on NM_018054.6) | Missense Mutation (SNP) | VAF 15/94 reads (16%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.037); catalogued as COSV99252878; called by muse, mutect2, varscan2
- ARHGEF28 | c.26C>T p.P9L | Missense Mutation (SNP) | VAF 4/39 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99708178; called by muse, mutect2, varscan2
- ASPM | c.7901A>G p.H2634R | Missense Mutation (SNP) | VAF 20/56 reads (36%) | SIFT tolerated (0.34); PolyPhen possibly damaging (0.83); catalogued as rs1396972656, COSV99659535, COSV99660773; called by muse, mutect2, varscan2
- ASPSCR1 | c.863G>T p.G288V | Missense Mutation (SNP) | VAF 18/160 reads (11%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.966); catalogued as rs1457794448, COSV100144689; called by muse, mutect2, varscan2
- ASTN2 | c.655C>A p.L219M | Missense Mutation (SNP) | VAF 5/43 reads (12%) | SIFT tolerated, low confidence (0.08); PolyPhen probably damaging (0.996); catalogued as COSV100524782; called by muse, mutect2, varscan2
- B4GALNT1 | c.255T>G p.S85R | Missense Mutation (SNP) | VAF 21/132 reads (16%) | SIFT tolerated (0.43); PolyPhen benign (0); catalogued as COSV100356349; called by muse, mutect2, varscan2
- BRD8 | c.1036G>T p.G346W (on ENST00000254900 / NM_139199.2; = p.G419W on NM_006696.4) | Missense Mutation (SNP) | VAF 37/109 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.919); catalogued as COSV99136588; called by muse, mutect2, varscan2
- BTNL3 | c.85C>A p.Q29K | Missense Mutation (SNP) | VAF 38/100 reads (38%) | SIFT tolerated (1); PolyPhen benign (0.157); catalogued as COSV100732170; called by muse, mutect2, varscan2
- C2CD3 | c.1907G>T p.W636L | Missense Mutation (SNP) | VAF 33/77 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100486248, COSV58093258; called by muse, mutect2, varscan2
- C2CD3 | c.1006A>G p.M336V | Missense Mutation (SNP) | VAF 7/61 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.881); catalogued as rs138239571, COSV100486249; called by muse, mutect2, varscan2
- C7orf33 | c.58C>A p.P20T | Missense Mutation (SNP) | VAF 12/75 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.855); catalogued as COSV100188696; called by muse, mutect2, varscan2
- C8A | c.766C>A p.P256T | Missense Mutation (SNP) | VAF 13/84 reads (15%) | SIFT tolerated (0.38); PolyPhen benign (0.109); catalogued as COSV100776438; called by muse, mutect2, varscan2
- CACNA2D1 | c.2407C>A p.Q803K (on ENST00000356253 / NM_001366867.1; = p.Q791K on NM_000722.4) | Missense Mutation (SNP) | VAF 12/136 reads (9%) | SIFT tolerated (0.43); PolyPhen benign (0.003); catalogued as COSV100665877, COSV100667146; called by muse, mutect2
- CACTIN | c.509G>T p.R170L | Missense Mutation (SNP) | VAF 6/20 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.891); catalogued as COSV99698279; called by muse, mutect2, varscan2
- CASP2 | c.908C>T p.A303V | Missense Mutation (SNP) | VAF 7/92 reads (8%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.679); catalogued as COSV100130851; called by muse, mutect2
- CCR10 | c.83C>T p.P28L | Missense Mutation (SNP) | VAF 7/65 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); catalogued as rs1382955227, COSV99226119; called by muse, mutect2
- CD163 | c.2212G>A p.G738S | Missense Mutation (SNP) | VAF 44/154 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.907); catalogued as COSV100775651; called by muse, mutect2, varscan2
- CD163 | c.1577C>G p.S526C | Missense Mutation (SNP) | VAF 9/83 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs765392469, COSV100775653; called by muse, mutect2, varscan2
- CD1A | c.263G>A p.R88H | Missense Mutation (SNP) | VAF 24/128 reads (19%) | SIFT tolerated (0.46); PolyPhen benign (0.022); catalogued as rs754517946, COSV56863073; called by muse, mutect2, varscan2
- CD1C | c.460G>T p.G154C | Missense Mutation (SNP) | VAF 59/426 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.335); catalogued as COSV100939351; called by mutect2, varscan2
- CDH3 | c.469G>A p.V157I | Missense Mutation (SNP) | VAF 8/156 reads (5%) | SIFT tolerated (0.47); PolyPhen benign (0.017); catalogued as COSV99867529; called by muse, mutect2
- CDHR1 | c.1097C>A p.S366Y | Missense Mutation (SNP) | VAF 5/65 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.73); catalogued as COSV100258414; called by muse, mutect2
- CDKAL1 | c.985G>T p.V329L | Missense Mutation (SNP) | VAF 38/101 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as COSV51180021, COSV99214080; called by muse, mutect2, varscan2
- CEMIP2 | c.3587G>C p.G1196A | Missense Mutation (SNP) | VAF 17/51 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.706); catalogued as COSV100987231, COSV65487104; called by muse, mutect2, varscan2
- CEP78 | c.709A>T p.N237Y | Missense Mutation (SNP) | VAF 13/66 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99449975; called by muse, mutect2, varscan2
- CGNL1 | c.1736A>G p.N579S | Missense Mutation (SNP) | VAF 10/49 reads (20%) | SIFT deleterious (0.04); PolyPhen benign (0.199); catalogued as rs1198987436, COSV99847478; called by muse, mutect2, varscan2
- CKAP2 | c.1966A>T p.T656S (on ENST00000378037 / NM_001098525.2; = p.T655S on NM_018204.5) | Missense Mutation (SNP) | VAF 23/114 reads (20%) | SIFT tolerated (0.79); PolyPhen benign (0.007); catalogued as COSV99318057; called by muse, mutect2, varscan2
- CLEC4C | c.511G>T p.G171C | Missense Mutation (SNP) | VAF 30/176 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as COSV100665350; called by muse, varscan2
- CLNK | c.600C>G p.P200= | Splice Region (SNP) | VAF 6/44 reads (14%) | catalogued as COSV99904558; called by muse, mutect2, varscan2
- CLNK | c.599C>A p.P200H | Missense Mutation (SNP) | VAF 6/44 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.72); catalogued as COSV99904559; called by muse, mutect2, varscan2
- CMAS | c.556G>T p.G186* | Nonsense Mutation (SNP) | VAF 32/79 reads (41%) | catalogued as COSV99982548; called by muse, mutect2, varscan2
- CMAS | c.557G>T p.G186V | Missense Mutation (SNP) | VAF 32/80 reads (40%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.89); catalogued as COSV99982549; called by muse, mutect2, varscan2
- CNR2 | c.20C>A p.T7K | Missense Mutation (SNP) | VAF 45/147 reads (31%) | SIFT tolerated (0.31); PolyPhen benign (0.007); catalogued as COSV100991242; called by muse, mutect2, varscan2
- CNTNAP5 | c.2883C>G p.S961R | Missense Mutation (SNP) | VAF 18/50 reads (36%) | SIFT deleterious (0.01); PolyPhen benign (0.372); catalogued as COSV101443058; called by muse, mutect2, varscan2
- COL11A1 | c.1737G>T p.R579S | Missense Mutation (SNP) | VAF 16/95 reads (17%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.977); catalogued as COSV100615147, COSV62187936; called by muse, mutect2, varscan2
- COL21A1 | c.2774G>T p.G925V | Missense Mutation (SNP) | VAF 7/17 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55174596, COSV99777457; called by muse, mutect2
- COL21A1 | c.2773G>T p.G925* | Nonsense Mutation (SNP) | VAF 6/15 reads (40%) | catalogued as COSV55169061, COSV99777458; called by muse, mutect2
- COL22A1 | c.2179C>A p.P727T | Missense Mutation (SNP) | VAF 28/76 reads (37%) | SIFT tolerated (0.37); PolyPhen possibly damaging (0.812); catalogued as COSV100276369; called by muse, mutect2, varscan2
- COL6A3 | c.8722G>A p.A2908T | Missense Mutation (SNP) | VAF 12/232 reads (5%) | SIFT tolerated (0.26); PolyPhen benign (0.052); catalogued as COSV99796204; called by muse, mutect2
- CPA2 | c.9G>A p.M3I | Missense Mutation (SNP) | VAF 30/152 reads (20%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.926); catalogued as COSV99743778; called by muse, varscan2
- CPZ | c.1799C>A p.P600H (on ENST00000360986 / NM_001014447.3; = p.P589H on NM_003652.3) | Missense Mutation (SNP) | VAF 20/50 reads (40%) | SIFT deleterious (0.01); PolyPhen benign (0); catalogued as COSV59923996; called by muse, mutect2, varscan2
- CRB2 | c.1960G>T p.A654S | Missense Mutation (SNP) | VAF 64/197 reads (32%) | SIFT tolerated (0.98); PolyPhen benign (0.003); catalogued as COSV100749522; called by muse, mutect2, varscan2
- CSMD3 | c.326C>G p.S109* | Nonsense Mutation (SNP) | VAF 18/103 reads (17%) | catalogued as COSV52104909, COSV99824995; called by muse, mutect2, varscan2
- CSNK1G3 | c.281G>T p.G94V | Missense Mutation (SNP) | VAF 29/44 reads (66%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.969); catalogued as COSV100631327; called by muse, mutect2, varscan2
- CTSO | c.732A>G p.I244M | Missense Mutation (SNP) | VAF 8/83 reads (10%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.657); catalogued as COSV70809887; called by muse, mutect2, varscan2
- CUBN | c.8374G>C p.G2792R | Missense Mutation (SNP) | VAF 33/115 reads (29%) | SIFT tolerated (0.24); PolyPhen benign (0.137); catalogued as COSV100912056; called by muse, mutect2, varscan2
- CXXC4 | c.583A>C p.T195P | Missense Mutation (SNP) | VAF 9/194 reads (5%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.705); catalogued as COSV101182252; called by muse, mutect2
- CYP2A13 | c.923C>A p.T308N | Missense Mutation (SNP) | VAF 9/77 reads (12%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.598); catalogued as COSV57839479; called by muse, mutect2, varscan2
- CYP3A4 | c.625A>G p.K209E | Missense Mutation (SNP) | VAF 14/117 reads (12%) | SIFT deleterious (0.03); PolyPhen benign (0.07); catalogued as COSV100315456; called by muse, mutect2, varscan2
- CYP3A5 | c.365A>T p.E122V | Missense Mutation (SNP) | VAF 9/96 reads (9%) | SIFT deleterious (0.03); PolyPhen benign (0.104); catalogued as COSV99769498; called by muse, mutect2
- DCC | c.3794T>C p.L1265P | Missense Mutation (SNP) | VAF 9/109 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV101472346, COSV71442599; called by muse, mutect2
- DCLRE1C | c.1643G>A p.S548N (on ENST00000378278 / NM_001350965.2; = p.S433N on NM_022487.4) | Missense Mutation (SNP) | VAF 18/104 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as rs1185331881, COSV100542982, COSV57954475; called by muse, mutect2, varscan2
- DDC | c.1009C>A p.H337N | Missense Mutation (SNP) | VAF 10/100 reads (10%) | SIFT tolerated (0.22); PolyPhen benign (0.043); catalogued as COSV100779121; called by muse, mutect2
- DDR2 | c.1359G>C p.M453I | Missense Mutation (SNP) | VAF 25/228 reads (11%) | SIFT tolerated (0.61); PolyPhen benign (0); catalogued as COSV100906194; called by muse, mutect2, varscan2
- DES | c.984C>G p.I328M | Missense Mutation (SNP) | VAF 15/36 reads (42%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.728); catalogued as COSV100900315; called by muse, mutect2, varscan2
- DLK1 | c.794C>T p.A265V | Missense Mutation (SNP) | VAF 25/85 reads (29%) | SIFT tolerated (0.33); PolyPhen benign (0.024); catalogued as COSV100375045; called by muse, mutect2, varscan2
- DNAH3 | c.9945G>T p.E3315D | Missense Mutation (SNP) | VAF 14/121 reads (12%) | SIFT tolerated (1); PolyPhen benign (0.02); catalogued as COSV99764971; called by muse, mutect2, varscan2
- DNAJC14 | c.255A>T p.R85S | Missense Mutation (SNP) | VAF 33/251 reads (13%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.015); catalogued as COSV100423514; called by muse, mutect2, varscan2
- DPYD | c.1441G>T p.D481Y | Missense Mutation (SNP) | VAF 24/105 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100928623; called by muse, mutect2, varscan2
- DSC2 | c.856G>T p.G286W | Missense Mutation (SNP) | VAF 24/104 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.84); catalogued as COSV99199473; called by muse, varscan2
- DST | c.8877C>A p.F2959L | Missense Mutation (SNP) | VAF 13/33 reads (39%) | SIFT tolerated, low confidence (0.85); PolyPhen benign (0.003); catalogued as COSV55029737, COSV99751129; called by muse, mutect2, varscan2
- EEF1A2 | c.364G>T p.E122* | Nonsense Mutation (SNP) | VAF 15/108 reads (14%) | catalogued as CM152982, COSV99419021; called by muse, mutect2, varscan2
- EEF1D | c.590C>G p.S197C | Missense Mutation (SNP) | VAF 22/71 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99434316; called by muse, mutect2, varscan2
- EHMT1 | c.3832G>T p.A1278S | Missense Mutation (SNP) | VAF 9/23 reads (39%) | SIFT tolerated (0.25); PolyPhen benign (0.003); catalogued as COSV101134992; called by muse, varscan2
- EPHB6 | c.695C>A p.T232N | Missense Mutation (SNP) | VAF 30/181 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.088); catalogued as COSV101235942; called by muse, mutect2, varscan2
- EVI2B | c.1201C>T p.L401F | Missense Mutation (SNP) | VAF 46/123 reads (37%) | SIFT tolerated (0.31); PolyPhen benign (0.006); catalogued as COSV100445379; called by muse, mutect2, varscan2
- FAM135B | c.958C>A p.Q320K | Missense Mutation (SNP) | VAF 9/58 reads (16%) | SIFT deleterious (0.03); PolyPhen benign (0.334); catalogued as COSV99418962; called by muse, mutect2, varscan2
- FAM221A | c.434C>G p.S145C | Missense Mutation (SNP) | VAF 37/146 reads (25%) | SIFT tolerated (0.16); PolyPhen benign (0.031); catalogued as COSV100794279; called by muse, mutect2, varscan2
- FAM53C | c.689G>T p.R230L | Missense Mutation (SNP) | VAF 63/148 reads (43%) | SIFT deleterious (0); PolyPhen benign (0.254); catalogued as COSV53510602, COSV99524214; called by muse, mutect2, varscan2
- FAT4 | c.5603A>T p.D1868V | Missense Mutation (SNP) | VAF 7/100 reads (7%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.999); catalogued as COSV100627233; called by muse, mutect2
- FBH1 | c.1483G>T p.A495S (on ENST00000362091 / NM_178150.3; = p.A546S on NM_032807.4) | Missense Mutation (SNP) | VAF 10/62 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.784); catalogued as COSV100758609, COSV62981860; called by muse, mutect2, varscan2
- FCRLA | c.313C>T p.L105F (on ENST00000367959; = p.L82F on NM_032738.4) | Missense Mutation (SNP) | VAF 31/66 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs767222473, COSV52684150; called by muse, mutect2, varscan2
- FERD3L | c.113C>G p.S38C | Missense Mutation (SNP) | VAF 15/56 reads (27%) | SIFT tolerated (0.1); PolyPhen benign (0.001); catalogued as COSV99284725; called by muse, mutect2, varscan2
- FMNL2 | c.1255A>C p.K419Q | Missense Mutation (SNP) | VAF 13/69 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99978918; called by muse, mutect2, varscan2
- FRMD6 | c.1220G>T p.G407V (on ENST00000344768 / NM_001267046.2; = p.G399V on NM_152330.4) | Missense Mutation (SNP) | VAF 8/64 reads (13%) | SIFT tolerated (0.1); PolyPhen benign (0.027); catalogued as COSV100655555; called by muse, mutect2
- FSCN3 | c.508G>A p.A170T | Missense Mutation (SNP) | VAF 8/76 reads (11%) | SIFT tolerated (0.35); PolyPhen probably damaging (0.912); catalogued as rs1378024231, COSV50001242; called by muse, mutect2, varscan2
- FYTTD1 | c.836A>C p.D279A | Missense Mutation (SNP) | VAF 8/61 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99611332; called by muse, mutect2, varscan2
- GABRA3 | c.920G>T p.R307L | Missense Mutation (SNP) | VAF 29/44 reads (66%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV100942437, COSV64805328; called by muse, mutect2, varscan2
- GALNT5 | c.1055G>T p.G352V | Missense Mutation (SNP) | VAF 26/123 reads (21%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.526); catalogued as rs1163201437, COSV99374844; called by muse, mutect2, varscan2
- GBP5 | c.1722G>T p.Q574H | Missense Mutation (SNP) | VAF 24/163 reads (15%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.478); catalogued as COSV100599977; called by muse, mutect2, varscan2
- GJA4 | c.701G>A p.R234H | Missense Mutation (SNP) | VAF 8/58 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0); catalogued as rs766402668, COSV100654622; called by muse, mutect2, varscan2
- GLI3 | c.3511G>T p.D1171Y | Missense Mutation (SNP) | VAF 21/174 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as COSV67895636; called by mutect2, varscan2
- GLRA2 | c.658C>A p.Q220K | Missense Mutation (SNP) | VAF 44/90 reads (49%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.893); catalogued as COSV99490253; called by muse, mutect2, varscan2
- GOLGA2 | c.1242A>T p.E414D | Missense Mutation (SNP) | VAF 15/151 reads (10%) | SIFT tolerated (0.33); PolyPhen benign (0.086); catalogued as COSV101363058; called by muse, mutect2, varscan2
- GRIA1 | c.1355A>G p.Y452C | Missense Mutation (SNP) | VAF 18/44 reads (41%) | SIFT deleterious (0.05); PolyPhen benign (0.013); catalogued as COSV99598137; called by muse, mutect2, varscan2
- GRIA1 | c.2489A>G p.Y830C | Missense Mutation (SNP) | VAF 90/176 reads (51%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.986); catalogued as COSV99598142; called by muse, mutect2, varscan2
- GRIN2A | c.2998G>A p.V1000M | Missense Mutation (SNP) | VAF 14/100 reads (14%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.998); catalogued as COSV58037528; called by muse, mutect2, varscan2
- HCFC1 | c.1437G>C p.R479S | Missense Mutation (SNP) | VAF 13/23 reads (57%) | SIFT tolerated (0.15); PolyPhen benign (0.019); catalogued as COSV100128432; called by muse, mutect2, varscan2
- HEPHL1 | c.2281G>A p.A761T | Missense Mutation (SNP) | VAF 9/96 reads (9%) | SIFT tolerated (0.52); PolyPhen benign (0.005); catalogued as rs774900315, COSV100243468; called by muse, mutect2
- HIVEP1 | c.5935G>T p.G1979C | Missense Mutation (SNP) | VAF 62/119 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV101044714; called by muse, mutect2, varscan2
- HRNR | c.1586G>T p.G529V | Missense Mutation (SNP) | VAF 21/457 reads (5%) | SIFT deleterious (0.02); PolyPhen benign (0.394); catalogued as COSV100912939; called by muse, mutect2
- HSPG2 | c.4798G>T p.G1600* | Nonsense Mutation (SNP) | VAF 34/83 reads (41%) | catalogued as COSV101020404; called by muse, mutect2, varscan2
- HTR1E | c.264G>T p.W88C | Missense Mutation (SNP) | VAF 18/105 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100540947, COSV59509289; called by muse, mutect2, varscan2
- HUS1B | c.113G>T p.S38I | Missense Mutation (SNP) | VAF 8/24 reads (33%) | SIFT deleterious (0.01); PolyPhen benign (0.029); catalogued as COSV100032816; called by muse, mutect2, varscan2
- IFI44L | c.724-1G>T p.X242_splice | Splice Site (SNP) | VAF 13/70 reads (19%) | catalogued as COSV100654872; called by muse, mutect2
- IGF2BP1 | c.1111G>T p.A371S | Missense Mutation (SNP) | VAF 39/96 reads (41%) | SIFT tolerated (0.87); PolyPhen benign (0.003); catalogued as COSV99288251; called by muse, mutect2, varscan2
- INTS4 | c.205G>A p.V69I | Missense Mutation (SNP) | VAF 15/109 reads (14%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.972); catalogued as rs144227709; called by muse, mutect2, varscan2
- ITGB2 | c.428T>C p.L143P | Missense Mutation (SNP) | VAF 6/97 reads (6%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.667); catalogued as COSV100185590; called by muse, mutect2
- JAK2 | c.712C>A p.Q238K | Missense Mutation (SNP) | VAF 16/114 reads (14%) | SIFT tolerated (0.86); PolyPhen benign (0.196); catalogued as COSV101070392, COSV67570296; called by muse, varscan2
- KAT2A | c.1273G>T p.G425W | Missense Mutation (SNP) | VAF 4/33 reads (12%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.844); catalogued as COSV99863373; called by muse, mutect2
- KCNB2 | c.2549G>A p.S850N | Missense Mutation (SNP) | VAF 25/98 reads (26%) | SIFT tolerated, low confidence (0.56); PolyPhen benign (0.034); catalogued as rs1401791514, COSV101578661; called by muse, mutect2, varscan2
- KCNE4 | c.243C>A p.S81R | Missense Mutation (SNP) | VAF 29/89 reads (33%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.632); catalogued as COSV56055599, COSV99919184; called by muse, mutect2, varscan2
- KCNQ2 | c.365C>A p.S122* | Nonsense Mutation (SNP) | VAF 29/119 reads (24%) | catalogued as CM068333, COSV100609686, COSV60435046; called by muse, mutect2, varscan2
- KCNS3 | c.515G>T p.W172L | Missense Mutation (SNP) | VAF 8/65 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV100410997; called by muse, mutect2, varscan2
- KEL | c.1191G>T p.E397D | Missense Mutation (SNP) | VAF 15/87 reads (17%) | SIFT tolerated (0.38); PolyPhen possibly damaging (0.596); catalogued as COSV100786868; called by muse, mutect2, varscan2
- KIAA1958 | c.1519A>T p.T507S | Missense Mutation (SNP) | VAF 5/37 reads (14%) | SIFT tolerated (0.52); PolyPhen benign (0); catalogued as COSV100515844; called by muse, mutect2
- KIF4B | c.2038C>T p.R680C | Missense Mutation (SNP) | VAF 48/107 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs369199447; called by muse, mutect2, varscan2
- KLHL32 | c.515C>A p.S172Y | Missense Mutation (SNP) | VAF 12/85 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.383); catalogued as COSV100987140; called by muse, mutect2, varscan2
- KLHL32 | c.1099A>G p.T367A | Missense Mutation (SNP) | VAF 25/55 reads (45%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.667); catalogued as COSV100987142; called by muse, mutect2, varscan2
- KRT6A | c.1620C>A p.S540R | Missense Mutation (SNP) | VAF 28/81 reads (35%) | SIFT tolerated (0.45); PolyPhen benign (0.249); catalogued as COSV100416690; called by muse, mutect2, varscan2
- KRT82 | c.476G>A p.R159K | Missense Mutation (SNP) | VAF 8/58 reads (14%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs1177293834, COSV99233384; called by muse, mutect2, varscan2
- KRTAP21-1 | c.29G>T p.C10F | Missense Mutation (SNP) | VAF 83/194 reads (43%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.217); catalogued as COSV100624898; called by muse, mutect2, varscan2
- LINC02210-CRHR1 | c.614G>T p.R205L | Missense Mutation (SNP) | VAF 14/52 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.897); catalogued as COSV99523308; called by muse, mutect2, varscan2
- LONRF2 | c.1759C>G p.L587V | Missense Mutation (SNP) | VAF 38/113 reads (34%) | SIFT deleterious (0.01); PolyPhen benign (0.062); catalogued as COSV101110852; called by muse, mutect2, varscan2
- LRCH1 | c.2008C>G p.L670V | Missense Mutation (SNP) | VAF 97/451 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.78); catalogued as COSV100243306; called by muse, varscan2
- LRP1B | c.9424G>T p.G3142* | Nonsense Mutation (SNP) | VAF 15/58 reads (26%) | catalogued as COSV67264764; called by muse, mutect2, varscan2
- LRRC7 | c.3386C>G p.P1129R (on ENST00000651989 / NM_001370785.2; = p.P1096R on NM_001330635.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 43/116 reads (37%) | SIFT tolerated (0.36); PolyPhen benign (0.111); catalogued as COSV99224510; called by muse, mutect2, varscan2
- LRRTM4 | c.1400G>T p.R467L | Missense Mutation (SNP) | VAF 19/60 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.883); catalogued as COSV101297423, COSV69138902, COSV69140714; called by muse, mutect2, varscan2
- MAD2L2 | c.173C>T p.P58L | Missense Mutation (SNP) | VAF 9/51 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs767807551, COSV99335768; called by muse, mutect2
- MALT1 | c.1924G>A p.D642N | Missense Mutation (SNP) | VAF 5/33 reads (15%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.911); catalogued as COSV61934034; called by muse, mutect2
- MAP2K3 | c.101C>G p.P34R (on ENST00000342679 / NM_145109.3; = p.P5R on NM_002756.4) | Missense Mutation (SNP) | VAF 24/157 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.54); catalogued as rs1403197048, COSV100383381; called by muse, mutect2, varscan2
- MAP2K6 | c.915C>A p.Y305* | Nonsense Mutation (SNP) | VAF 22/189 reads (12%) | catalogued as COSV100765032; called by muse, mutect2, varscan2
- MAP4 | c.1555G>T p.D519Y | Missense Mutation (SNP) | VAF 15/109 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.885); catalogued as COSV100805418; called by muse, mutect2, varscan2
- MATK | c.835G>T p.V279F (on ENST00000310132 / NM_139355.3; = p.V280F on NM_002378.4) | Missense Mutation (SNP) | VAF 8/36 reads (22%) | SIFT tolerated (0.11); PolyPhen benign (0.261); catalogued as COSV100035840; called by muse, mutect2, varscan2
- MCAM | c.1164G>T p.R388S | Missense Mutation (SNP) | VAF 23/136 reads (17%) | SIFT tolerated (0.27); PolyPhen benign (0.103); catalogued as COSV99875479; called by muse, mutect2, varscan2
- MGAM | c.5282A>T p.Y1761F | Missense Mutation (SNP) | VAF 4/26 reads (15%) | SIFT tolerated (0.2); PolyPhen benign (0.007); catalogued as COSV101527374; called by muse, mutect2
- MIA3 | c.5692G>C p.D1898H | Missense Mutation (SNP) | VAF 11/201 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV100388040; called by muse, mutect2
- MORN5 | c.355G>T p.G119C | Missense Mutation (SNP) | VAF 11/116 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV101055663; called by muse, mutect2
- MUC16 | c.18076C>T p.H6026Y | Missense Mutation (SNP) | VAF 42/168 reads (25%) | SIFT tolerated, low confidence (0.34); PolyPhen benign (0.006); catalogued as rs776109452, COSV101198108; called by muse, mutect2, varscan2
- MUC17 | c.11650A>G p.T3884A | Missense Mutation (SNP) | VAF 17/187 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.542); catalogued as COSV100071614; called by muse, mutect2
- MYBPC3 | c.2233G>A p.D745N | Missense Mutation (SNP) | VAF 14/44 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV57026124, COSV99919914; called by muse, mutect2, varscan2
- MYL7 | c.378-2A>T p.X126_splice | Splice Site (SNP) | VAF 15/103 reads (15%) | catalogued as COSV99789909; called by muse, mutect2, varscan2
- MYO1B | c.1463A>G p.H488R | Missense Mutation (SNP) | VAF 48/271 reads (18%) | SIFT deleterious (0.04); PolyPhen benign (0.16); catalogued as COSV100268637; called by muse, mutect2, varscan2
- MYO3B | c.2493C>A p.C831* | Nonsense Mutation (SNP) | VAF 17/90 reads (19%) | catalogued as COSV100509190; called by muse, mutect2, varscan2
- MYT1L | c.2664A>C p.K888N | Missense Mutation (SNP) | VAF 6/54 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.777); catalogued as COSV101218853; called by muse, mutect2, varscan2
- NAV3 | c.79C>A p.P27T | Missense Mutation (SNP) | VAF 78/228 reads (34%) | SIFT tolerated, low confidence (0.07); PolyPhen probably damaging (0.994); catalogued as COSV99887018; called by muse, mutect2, varscan2
- NAV3 | c.2113G>A p.G705R | Missense Mutation (SNP) | VAF 8/60 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99887021; called by muse, mutect2
- NBEAL2 | c.4537G>A p.V1513M | Missense Mutation (SNP) | VAF 26/65 reads (40%) | SIFT tolerated (0.24); PolyPhen benign (0); catalogued as rs367809683; called by muse, mutect2, varscan2
- NDST4 | c.2286G>A p.Q762= | Splice Region (SNP) | VAF 17/105 reads (16%) | catalogued as COSV99079523, COSV99995478; called by muse, mutect2, varscan2
- NEK4 | c.485T>C p.M162T | Missense Mutation (SNP) | VAF 25/57 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV99237186; called by muse, mutect2, varscan2
- NFASC | c.494C>A p.P165Q (on ENST00000339876 / NM_001378329.1; = p.P159Q on NM_015090.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 52/214 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100362806, COSV58359668; called by muse, varscan2
- NINL | c.2680G>T p.A894S | Missense Mutation (SNP) | VAF 7/23 reads (30%) | SIFT tolerated (0.31); PolyPhen benign (0.118); catalogued as COSV99624585; called by muse, mutect2, varscan2
- NKD2 | c.818C>T p.P273L | Missense Mutation (SNP) | VAF 4/32 reads (13%) | SIFT tolerated (0.72); PolyPhen benign (0.368); catalogued as COSV99723795; called by muse, mutect2
- NLRP10 | c.389C>T p.P130L | Missense Mutation (SNP) | VAF 13/61 reads (21%) | SIFT tolerated (0.07); PolyPhen benign (0.147); catalogued as COSV100149472; called by muse, mutect2, varscan2
- NLRP14 | c.14C>T p.S5L | Missense Mutation (SNP) | VAF 12/115 reads (10%) | SIFT tolerated (0.22); PolyPhen benign (0.001); catalogued as rs1204806522, COSV55063581; called by muse, mutect2, varscan2
- NLRP2 | c.1669T>A p.S557T | Missense Mutation (SNP) | VAF 12/80 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.028); catalogued as COSV99671885; called by muse, mutect2, varscan2
- NLRP4 | c.2656C>T p.R886W | Missense Mutation (SNP) | VAF 12/134 reads (9%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.606); catalogued as rs147716168; called by muse, mutect2
- NPY5R | c.143A>G p.Y48C | Missense Mutation (SNP) | VAF 20/154 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100642639; called by muse, mutect2, varscan2
- NRXN1 | c.3150A>T p.Q1050H | Missense Mutation (SNP) | VAF 8/59 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as COSV100453350; called by muse, mutect2, varscan2
- NTRK3 | c.1387G>T p.G463* | Nonsense Mutation (SNP) | VAF 8/33 reads (24%) | catalogued as COSV100445429; called by muse, mutect2, varscan2
- OPHN1 | c.567G>T p.Q189H | Missense Mutation (SNP) | VAF 5/14 reads (36%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.993); catalogued as COSV100830213; called by muse, mutect2, varscan2
- OR10G9 | c.616G>T p.A206S | Missense Mutation (SNP) | VAF 27/213 reads (13%) | SIFT tolerated (0.42); PolyPhen benign (0.103); catalogued as COSV100901475; called by muse, mutect2, varscan2
- OR10J3 | c.679C>A p.L227I | Missense Mutation (SNP) | VAF 91/168 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV100171598, COSV59955282; called by muse, mutect2, varscan2
- OR10X1 | c.317G>A p.R106K | Missense Mutation (SNP) | VAF 9/123 reads (7%) | SIFT tolerated (0.25); PolyPhen benign (0.003); catalogued as COSV63766985; called by muse, mutect2
- OR1A2 | c.883A>T p.M295L | Missense Mutation (SNP) | VAF 57/111 reads (51%) | SIFT tolerated (0.2); PolyPhen benign (0.031); catalogued as COSV101126336; called by muse, mutect2, varscan2
- OR1J4 | c.290G>T p.C97F | Missense Mutation (SNP) | VAF 79/251 reads (31%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.962); catalogued as rs1325293336, COSV100534239; called by muse, mutect2, varscan2
- OR2A25 | c.598G>T p.A200S | Missense Mutation (SNP) | VAF 26/195 reads (13%) | SIFT tolerated (0.08); PolyPhen benign (0.072); catalogued as COSV68717184; called by muse, mutect2, varscan2
- OR2F1 | c.416G>T p.G139V | Missense Mutation (SNP) | VAF 7/128 reads (5%) | SIFT tolerated (0.29); PolyPhen benign (0.053); catalogued as COSV101231285, COSV101231334; called by muse, mutect2
- OR2G2 | c.898G>C p.V300L | Missense Mutation (SNP) | VAF 45/169 reads (27%) | SIFT deleterious (0.01); PolyPhen benign (0.06); catalogued as COSV100189569; called by muse, mutect2, varscan2
- OR4A15 | c.833C>A p.P278H | Missense Mutation (SNP) | VAF 50/221 reads (23%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.816); catalogued as COSV100123832; called by muse, mutect2
- OR4K17 | c.315C>G p.H105Q | Missense Mutation (SNP) | VAF 34/179 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.882); catalogued as COSV100210498; called by muse, mutect2, varscan2
- OR4N5 | c.750G>T p.M250I | Missense Mutation (SNP) | VAF 151/373 reads (40%) | SIFT tolerated (0.51); PolyPhen probably damaging (0.989); catalogued as COSV100374017; called by muse, mutect2, varscan2
- OR6B3 | c.193T>A p.S65T | Missense Mutation (SNP) | VAF 22/93 reads (24%) | SIFT tolerated (0.09); PolyPhen benign (0.006); catalogued as COSV100096903; called by muse, mutect2, varscan2
- OR6F1 | c.470C>G p.A157G | Missense Mutation (SNP) | VAF 30/115 reads (26%) | SIFT tolerated (0.23); PolyPhen benign (0.089); catalogued as COSV100128953; called by muse, mutect2, varscan2
- OR6K2 | c.235C>G p.P79A | Missense Mutation (SNP) | VAF 18/157 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1366888965, COSV100656685, COSV62743508; called by muse, mutect2, varscan2
- OR6K6 | c.126C>G p.F42L (on ENST00000368144; = p.F18L on NM_001005184.1) | Missense Mutation (SNP) | VAF 18/278 reads (6%) | SIFT tolerated (0.48); PolyPhen probably damaging (0.998); catalogued as COSV100933681; called by muse, mutect2
- OR8B8 | c.853C>A p.L285I | Missense Mutation (SNP) | VAF 32/99 reads (32%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.682); catalogued as COSV100044817; called by muse, mutect2, varscan2
- ORC1 | c.2173A>G p.I725V | Missense Mutation (SNP) | VAF 36/94 reads (38%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.925); catalogued as rs539320346, COSV100856584; called by muse, mutect2, varscan2
- PAPPA2 | c.2405C>T p.P802L | Missense Mutation (SNP) | VAF 9/134 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs866338265, COSV62778802; called by muse, mutect2
- PAPPA2 | c.4486C>T p.P1496S | Missense Mutation (SNP) | VAF 44/213 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.898); catalogued as rs1292073684, COSV100867575; called by muse, mutect2, varscan2
- PAPPA2 | c.4793C>A p.P1598H | Missense Mutation (SNP) | VAF 30/139 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.984); catalogued as rs1170466523, COSV62804869; called by muse, mutect2
- PAPSS2 | c.1309C>T p.P437S | Missense Mutation (SNP) | VAF 12/96 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs755518410, COSV100753414; called by muse, mutect2, varscan2
- PARN | c.1830A>T p.K610N | Missense Mutation (SNP) | VAF 20/86 reads (23%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.001); catalogued as COSV100420649; called by muse, mutect2, varscan2
- PCDH10 | c.1261C>A p.L421M | Missense Mutation (SNP) | VAF 49/268 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52091853, COSV99992976; called by muse, varscan2
- PCDHB7 | c.1432A>T p.R478* | Nonsense Mutation (SNP) | VAF 38/125 reads (30%) | catalogued as rs782428202, COSV99175637; called by muse, mutect2, varscan2
- PCLO | c.14716C>G p.Q4906E | Missense Mutation (SNP) | VAF 31/261 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.921); catalogued as COSV100427464; called by muse, mutect2, varscan2
- PCLO | c.5057A>G p.Q1686R | Missense Mutation (SNP) | VAF 20/75 reads (27%) | SIFT deleterious (0.05); PolyPhen benign (0.009); catalogued as COSV100427467; called by muse, mutect2, varscan2
- PDCD11 | c.779C>T p.S260L | Missense Mutation (SNP) | VAF 14/80 reads (18%) | SIFT tolerated (0.12); PolyPhen benign (0.001); catalogued as COSV100874239, COSV100874243, COSV100874365; called by muse, mutect2, varscan2
- PEX5L | c.1285T>C p.Y429H | Missense Mutation (SNP) | VAF 6/92 reads (7%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV99827936; called by muse, mutect2
- PGR | c.2191A>T p.K731* | Nonsense Mutation (SNP) | VAF 65/213 reads (31%) | catalogued as COSV99677442; called by muse, mutect2, varscan2
- PHLPP2 | c.1591G>C p.D531H | Missense Mutation (SNP) | VAF 11/88 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV100673495; called by muse, mutect2, varscan2
- PKD1L1 | c.1174G>C p.E392Q | Missense Mutation (SNP) | VAF 18/113 reads (16%) | SIFT tolerated, low confidence (0.37); PolyPhen benign (0.022); catalogued as rs1337575533, COSV99218449; called by muse, mutect2, varscan2
- PLA2G3 | c.590A>T p.N197I | Missense Mutation (SNP) | VAF 64/119 reads (54%) | SIFT deleterious (0); PolyPhen possibly damaging (0.876); catalogued as COSV53208676, COSV99311315; called by muse, mutect2, varscan2
- PLCL1 | c.2335G>T p.D779Y | Missense Mutation (SNP) | VAF 27/172 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101406790, COSV101407189; called by muse, mutect2, varscan2
- PLS1 | c.1787C>G p.A596G | Missense Mutation (SNP) | VAF 49/154 reads (32%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.456); catalogued as rs1338756658, COSV100537954; called by muse, mutect2, varscan2
- POPDC2 | c.546C>A p.F182L | Missense Mutation (SNP) | VAF 17/57 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.755); catalogued as COSV51742353; called by muse, mutect2, varscan2
- POTED | c.326G>A p.C109Y | Missense Mutation (SNP) | VAF 7/32 reads (22%) | SIFT tolerated, low confidence (0.06); PolyPhen possibly damaging (0.831); catalogued as COSV100203005; called by muse, mutect2, varscan2
- PPFIA1 | c.532-1G>T p.X178_splice | Splice Site (SNP) | VAF 52/132 reads (39%) | catalogued as COSV99556849; called by muse, varscan2
- PPM1E | c.1679A>G p.Q560R | Missense Mutation (SNP) | VAF 32/96 reads (33%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.003); catalogued as COSV100375807; called by muse, mutect2, varscan2
- PRCP | c.1137G>A p.M379I | Missense Mutation (SNP) | VAF 14/62 reads (23%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.832); catalogued as rs1460240727, COSV100475659; called by muse, mutect2, varscan2
- PROM1 | c.1613G>T p.W538L | Missense Mutation (SNP) | VAF 4/23 reads (17%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.627); catalogued as COSV101477041; called by muse, mutect2
- PRRC2C | c.2217G>T p.W739C (on ENST00000367742; = p.W737C on NM_015172.4) | Missense Mutation (SNP) | VAF 13/27 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100144664; called by muse, mutect2, varscan2
- PRSS1 | c.417C>A p.C139* | Nonsense Mutation (SNP) | VAF 29/125 reads (23%) | catalogued as rs141847266, COSV100297710, COSV104411416; called by muse, mutect2, varscan2
- PRUNE2 | c.8074T>A p.S2692T | Missense Mutation (SNP) | VAF 16/107 reads (15%) | SIFT tolerated (0.22); PolyPhen benign (0.044); catalogued as COSV100944224; called by muse, mutect2
- PTPRJ | c.3406A>G p.I1136V | Missense Mutation (SNP) | VAF 11/162 reads (7%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV101394466; called by muse, mutect2
- PUS1 | c.427G>T p.A143S | Missense Mutation (SNP) | VAF 8/36 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as COSV100435125, COSV59035032; called by muse, mutect2, varscan2
- PXDNL | c.1243G>T p.V415L | Missense Mutation (SNP) | VAF 10/50 reads (20%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.893); catalogued as rs1563418784, COSV100681442; called by muse, mutect2, varscan2
- R3HDM2 | c.1837C>T p.P613S | Missense Mutation (SNP) | VAF 12/58 reads (21%) | SIFT tolerated (0.71); PolyPhen probably damaging (0.996); catalogued as COSV61295802; called by muse, mutect2, varscan2
- RAB28 | c.532C>T p.L178F | Missense Mutation (SNP) | VAF 15/74 reads (20%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.923); catalogued as rs375680071, COSV99986038; called by muse, mutect2, varscan2
- RASSF9 | c.48A>G p.R16= | Splice Region (SNP) | VAF 9/63 reads (14%) | catalogued as COSV100771198; called by muse, mutect2, varscan2
- RBM19 | c.1205G>T p.G402V | Missense Mutation (SNP) | VAF 15/103 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV99925517; called by muse, mutect2, varscan2
- RBM19 | c.1204G>T p.G402* | Nonsense Mutation (SNP) | VAF 15/105 reads (14%) | catalogued as COSV99925518; called by muse, mutect2, varscan2
- REG3A | c.196-1G>A p.X66_splice | Splice Site (SNP) | VAF 11/95 reads (12%) | catalogued as COSV100532547, COSV100532917; called by muse, mutect2
- RESF1 | c.5069A>C p.K1690T | Missense Mutation (SNP) | VAF 8/55 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.106); catalogued as COSV100440096; called by muse, mutect2, varscan2
- RHOH | c.380G>T p.R127M | Missense Mutation (SNP) | VAF 18/56 reads (32%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.811); catalogued as COSV101110382; called by muse, mutect2, varscan2
- RIMBP2 | c.2281G>A p.E761K | Missense Mutation (SNP) | VAF 8/79 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1177409370, COSV55470357; called by muse, mutect2
- RNF213 | c.9485C>T p.P3162L | Missense Mutation (SNP) | VAF 10/77 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100299728; called by muse, mutect2
- RP1L1 | c.1486G>C p.G496R | Missense Mutation (SNP) | VAF 13/49 reads (27%) | SIFT deleterious (0.03); PolyPhen benign (0.056); catalogued as COSV101222954; called by muse, mutect2, varscan2
- RPL3L | c.1216G>T p.D406Y | Missense Mutation (SNP) | VAF 40/179 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.284); catalogued as COSV51908545; called by muse, mutect2, varscan2
- SATL1 | c.833G>T p.S278I (on ENST00000395409; = p.S465I on NM_001012980.2) | Missense Mutation (SNP) | VAF 16/72 reads (22%) | SIFT tolerated (0.29); PolyPhen benign (0.136); catalogued as COSV100260672; called by muse, varscan2
- SCN11A | c.84G>T p.E28D | Missense Mutation (SNP) | VAF 7/122 reads (6%) | SIFT deleterious (0.02); PolyPhen benign (0.03); catalogued as COSV100180972; called by muse, mutect2
- SEPTIN10 | c.703C>T p.Q235* | Nonsense Mutation (SNP) | VAF 18/119 reads (15%) | catalogued as rs752368017, COSV100453865; called by muse, mutect2, varscan2
- SERPINA3 | c.274C>T p.H92Y | Missense Mutation (SNP) | VAF 14/107 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.041); catalogued as COSV101261609; called by muse, mutect2, varscan2
- SERPING1 | c.1211C>T p.T404M | Missense Mutation (SNP) | VAF 25/105 reads (24%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.967); catalogued as rs373751057, COSV99557825; called by muse, mutect2, varscan2
- SLC12A5 | c.1495G>T p.V499L (on ENST00000454036 / NM_001134771.2; = p.V476L on NM_020708.5) | Missense Mutation (SNP) | VAF 38/187 reads (20%) | SIFT tolerated (0.1); PolyPhen benign (0.072); catalogued as COSV99715368; called by muse, mutect2, varscan2
- SLC12A7 | c.436G>T p.G146W | Missense Mutation (SNP) | VAF 22/95 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99369317; called by muse, mutect2, varscan2
- SLC1A1 | c.858G>T p.M286I | Missense Mutation (SNP) | VAF 46/139 reads (33%) | SIFT deleterious (0.01); PolyPhen benign (0.081); catalogued as COSV99261161; called by muse, varscan2
- SLC23A1 | c.465+4G>T | Splice Region (SNP) | VAF 13/58 reads (22%) | catalogued as COSV100811866; called by muse, mutect2, varscan2
- SLC7A1 | c.1501A>T p.S501C | Missense Mutation (SNP) | VAF 32/139 reads (23%) | SIFT tolerated (0.21); PolyPhen benign (0.007); catalogued as COSV101060129, COSV101060143; called by muse, mutect2, varscan2
- SLC8A1 | c.1672G>T p.V558L | Missense Mutation (SNP) | VAF 16/162 reads (10%) | SIFT tolerated (0.4); PolyPhen benign (0.034); catalogued as COSV100244539; called by muse, mutect2
- SLCO1B3 | c.2014G>T p.E672* | Nonsense Mutation (SNP) | VAF 43/83 reads (52%) | catalogued as COSV99680707; called by muse, mutect2, varscan2
- SMARCD2 | c.1053G>C p.E351D | Missense Mutation (SNP) | VAF 12/20 reads (60%) | SIFT tolerated (0.29); PolyPhen probably damaging (0.996); catalogued as COSV99856209; called by muse, varscan2
- SMG1 | c.7690A>G p.I2564V | Missense Mutation (SNP) | VAF 22/86 reads (26%) | SIFT tolerated (0.19); PolyPhen benign (0.314); catalogued as COSV101245186; called by muse, mutect2, varscan2
- SNTA1 | c.395G>C p.G132A | Missense Mutation (SNP) | VAF 16/218 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV99458554; called by muse, mutect2
- SNTG2 | c.538T>C p.S180P | Missense Mutation (SNP) | VAF 48/267 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.832); catalogued as COSV100421455; called by muse, mutect2, varscan2
- SORBS2 | c.1787C>G p.S596C | Missense Mutation (SNP) | VAF 8/59 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV99509527; called by muse, mutect2, varscan2
- SPATA5 | c.1760C>A p.P587H | Missense Mutation (SNP) | VAF 16/54 reads (30%) | SIFT tolerated (0.05); PolyPhen benign (0.235); catalogued as COSV99914759; called by muse, mutect2
- SPDL1 | c.3G>T p.M1? | Translation Start Site (SNP) | VAF 9/42 reads (21%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.306); catalogued as COSV99517386; called by muse, mutect2, varscan2
- SPECC1 | c.3117+1del | Frame Shift Del (DEL) | VAF 25/78 reads (32%) | catalogued as COSV99821724; called by mutect2, pindel, varscan2
- SPTA1 | c.2722C>A p.L908M | Missense Mutation (SNP) | VAF 26/285 reads (9%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.986); catalogued as COSV63760800; called by muse, mutect2
- ST6GAL2 | c.634G>A p.V212I | Missense Mutation (SNP) | VAF 15/58 reads (26%) | PolyPhen benign (0.217); catalogued as rs1386522472, COSV100867661; called by muse, mutect2, varscan2
- STT3A | c.954G>T p.M318I | Missense Mutation (SNP) | VAF 37/119 reads (31%) | SIFT tolerated (0.11); PolyPhen benign (0.012); catalogued as COSV101205111; called by muse, mutect2, varscan2
- TAS1R2 | c.1874C>T p.P625L | Missense Mutation (SNP) | VAF 17/106 reads (16%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.889); catalogued as COSV100946136; called by muse, mutect2, varscan2
- TCF23 | c.546C>A p.S182R | Missense Mutation (SNP) | VAF 34/102 reads (33%) | SIFT deleterious (0.01); PolyPhen benign (0.031); catalogued as COSV99940274; called by muse, mutect2, varscan2
- TET3 | c.1147C>G p.P383A | Missense Mutation (SNP) | VAF 34/93 reads (37%) | SIFT tolerated (0.11); PolyPhen benign (0.077); catalogued as COSV99996171; called by muse, mutect2, varscan2
- TEX55 | c.133A>C p.N45H | Missense Mutation (SNP) | VAF 3/43 reads (7%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.697); catalogued as COSV99817294; called by muse, mutect2
- THBS2 | c.3161C>A p.P1054H | Missense Mutation (SNP) | VAF 19/34 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV100827598; called by muse, mutect2, varscan2
- THEM4 | c.475A>G p.M159V | Missense Mutation (SNP) | VAF 62/114 reads (54%) | SIFT deleterious (0.05); PolyPhen benign (0.049); catalogued as COSV100916892; called by muse, mutect2, varscan2
- TLR4 | c.552C>A p.S184R (on ENST00000355622 / NM_138554.5; = p.S144R on NM_003266.4) | Missense Mutation (SNP) | VAF 29/123 reads (24%) | SIFT tolerated (0.2); PolyPhen benign (0.272); catalogued as COSV100790602; called by muse, mutect2, varscan2
- TMC2 | c.1739del p.G580Afs*5 | Frame Shift Del (DEL) | VAF 9/85 reads (11%) | catalogued as COSV99072193; called by mutect2, pindel, varscan2
- TMEM131 | c.3989C>T p.S1330F | Missense Mutation (SNP) | VAF 4/35 reads (11%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.172); catalogued as COSV99486559; called by muse, mutect2
- TMEM245 | c.2316A>T p.L772F | Missense Mutation (SNP) | VAF 8/58 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.187); catalogued as COSV101002196; called by muse, mutect2, varscan2
- TNFAIP1 | c.245C>A p.T82N | Missense Mutation (SNP) | VAF 35/135 reads (26%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.493); catalogued as COSV99880181; called by muse, mutect2, varscan2
- TNR | c.4040T>A p.L1347H | Missense Mutation (SNP) | VAF 12/137 reads (9%) | SIFT deleterious (0.03); PolyPhen benign (0.039); catalogued as COSV99687632; called by muse, mutect2
- TOP1 | c.901G>C p.D301H | Missense Mutation (SNP) | VAF 24/84 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV100793673; called by muse, mutect2, varscan2
- TPCN2 | c.358C>G p.P120A | Missense Mutation (SNP) | VAF 16/108 reads (15%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.493); catalogued as COSV53730510, COSV99593184; called by muse, varscan2
- TRIM48 | c.519C>A p.N173K | Missense Mutation (SNP) | VAF 8/43 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.082); catalogued as COSV70161194; called by muse, mutect2, varscan2
- TRPM1 | c.3211C>A p.L1071M | Missense Mutation (SNP) | VAF 8/56 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.988); catalogued as COSV99855347; called by muse, mutect2, varscan2
- TRPM3 | c.606G>T p.K202N (on ENST00000357533 / NM_001366142.2; = p.K47N on NM_020952.6) | Missense Mutation (SNP) | VAF 49/207 reads (24%) | SIFT deleterious (0.03); PolyPhen benign (0.063); catalogued as COSV100624048; called by muse, mutect2, varscan2
- TRPV6 | c.490G>A p.A164T | Missense Mutation (SNP) | VAF 34/84 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.763); catalogued as rs769078836, COSV100844126; called by muse, mutect2, varscan2
- TSHZ3 | c.2957G>C p.R986T | Missense Mutation (SNP) | VAF 12/69 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as COSV99550639; called by muse, mutect2, varscan2
- TTK | c.185C>T p.P62L | Missense Mutation (SNP) | VAF 12/49 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100035972; called by muse, mutect2, varscan2
- TTN | c.77054A>C p.K25685T (on ENST00000591111; = p.K18261T on NM_003319.4) | Missense Mutation (SNP) | VAF 26/232 reads (11%) | PolyPhen probably damaging (0.923); catalogued as COSV60284752; called by muse, mutect2, varscan2
- UBXN4 | c.1073G>T p.G358V | Missense Mutation (SNP) | VAF 16/109 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs373377908; called by muse, mutect2, varscan2
- UNC13C | c.643G>T p.D215Y | Missense Mutation (SNP) | VAF 34/88 reads (39%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.936); catalogued as COSV99511807; called by muse, mutect2, varscan2
- USH2A | c.13693T>G p.Y4565D | Missense Mutation (SNP) | VAF 9/184 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV100229070; called by muse, mutect2
- VCAN | c.223G>A p.G75R | Missense Mutation (SNP) | VAF 7/118 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV99424659; called by muse, mutect2
- VPS13B | c.73G>A p.D25N | Missense Mutation (SNP) | VAF 49/269 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100660876; called by muse, mutect2, varscan2
- VPS13B | c.4412G>C p.R1471P | Missense Mutation (SNP) | VAF 34/157 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV100660877; called by muse, mutect2, varscan2
- VPS50 | c.2864C>A p.A955D | Missense Mutation (SNP) | VAF 26/155 reads (17%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as COSV100004504; called by muse, mutect2, varscan2
- WDR47 | c.2296G>A p.G766S (on ENST00000369962 / NM_001142551.2; = p.G767S on NM_014969.5) | Missense Mutation (SNP) | VAF 10/158 reads (6%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.913); catalogued as COSV100728233; called by muse, mutect2
- WWOX | c.439C>T p.H147Y | Missense Mutation (SNP) | VAF 12/28 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as rs746480783, COSV100880156; called by muse, mutect2, varscan2
- ZBED6CL | c.314A>G p.Y105C | Missense Mutation (SNP) | VAF 10/85 reads (12%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.98); catalogued as COSV100550320; called by muse, mutect2, varscan2
- ZDBF2 | c.2702A>C p.Q901P | Missense Mutation (SNP) | VAF 8/61 reads (13%) | SIFT tolerated (0.13); PolyPhen benign (0.005); catalogued as COSV100984350; called by muse, mutect2, varscan2
- ZDBF2 | c.5195T>G p.L1732R | Missense Mutation (SNP) | VAF 6/74 reads (8%) | SIFT tolerated (0.07); PolyPhen benign (0.056); catalogued as COSV100984351, COSV100985712; called by muse, mutect2
- ZNF155 | c.1462G>T p.D488Y | Missense Mutation (SNP) | VAF 8/160 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.956); catalogued as COSV99525512; called by muse, mutect2
- ZNF536 | c.3818C>T p.S1273F | Missense Mutation (SNP) | VAF 9/63 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.172); catalogued as rs866481206, COSV62827382, COSV99052783; called by muse, mutect2, varscan2
- ZNF560 | c.631G>A p.E211K | Missense Mutation (SNP) | VAF 18/62 reads (29%) | SIFT tolerated (1); PolyPhen benign (0.164); catalogued as COSV100038235; called by muse, mutect2, varscan2
- ZNF618 | c.1723C>A p.H575N (on ENST00000374126 / NM_001318042.2; = p.H482N on NM_133374.2) | Missense Mutation (SNP) | VAF 10/33 reads (30%) | SIFT tolerated (0.13); PolyPhen benign (0.053); catalogued as COSV99929236; called by muse, mutect2, varscan2
- ZNF804A | c.2726A>T p.D909V | Missense Mutation (SNP) | VAF 14/104 reads (13%) | SIFT deleterious (0.02); PolyPhen benign (0.143); catalogued as COSV100166439; called by muse, mutect2, varscan2
- ZSCAN20 | c.1133A>G p.Y378C | Missense Mutation (SNP) | VAF 22/140 reads (16%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.999); catalogued as rs529615717, COSV100792485; called by muse, mutect2, varscan2
- ARID4A | c.2171dup p.N724Kfs*2 | Frame Shift Ins (INS) | VAF 12/86 reads (14%) | called by mutect2, varscan2
- ARNTL2 | c.1709G>T p.G570V | Missense Mutation (SNP) | VAF 12/109 reads (11%) | SIFT deleterious (0.04); PolyPhen benign (0.368); called by muse, mutect2, varscan2
- CCL18 | c.16G>T p.A6S | Missense Mutation (SNP) | VAF 28/152 reads (18%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.505); called by muse, mutect2, varscan2
- CHRNA9 | c.188del p.T63Sfs*15 | Frame Shift Del (DEL) | VAF 18/147 reads (12%) | called by mutect2, pindel, varscan2
- COL26A1 | c.1186G>T p.G396* (on ENST00000313669 / NM_001278563.3; = p.G394* on NM_133457.4) | Nonsense Mutation (SNP) | VAF 6/27 reads (22%) | called by muse, mutect2, varscan2
- CPNE4 | c.595del p.V199* | Frame Shift Del (DEL) | VAF 8/79 reads (10%) | called by mutect2, pindel, varscan2
- FCGBP | c.1174T>A p.S392T | Missense Mutation (SNP) | VAF 8/36 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- FLNA | c.7774G>A p.V2592M (on ENST00000369850 / NM_001110556.2; = p.V2584M on NM_001456.3) | Missense Mutation (SNP) | VAF 16/23 reads (70%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- IGHV2-26 | c.107C>T p.T36I | Missense Mutation (SNP) | VAF 3/34 reads (9%) | SIFT deleterious (0.02); PolyPhen benign (0.034); called by muse, mutect2
- ISOC2 | c.82del p.R28Afs*30 | Frame Shift Del (DEL) | VAF 13/87 reads (15%) | called by mutect2, pindel, varscan2
- MRC1 | c.3779C>A p.S1260Y | Missense Mutation (SNP) | VAF 159/449 reads (35%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.841); called by muse, mutect2, varscan2
- PAQR6 | c.543T>G p.S181R (on ENST00000292291 / NM_001272108.2; = p.S75R on NM_024897.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 5/98 reads (5%) | SIFT tolerated (0.17); PolyPhen benign (0.055); called by muse, mutect2
- PRLHR | c.996del p.F333Sfs*25 | Frame Shift Del (DEL) | VAF 6/68 reads (9%) | called by mutect2, pindel
- RND2 | c.104_107delinsCACG p.S35_Y36delinsTR | Missense Mutation (ONP) | VAF 7/69 reads (10%) | called by mutect2*, pindel
- SLC18A3 | c.315del p.W105Cfs*18 | Frame Shift Del (DEL) | VAF 14/78 reads (18%) | called by mutect2, pindel, varscan2
- TRAV30 | c.228G>T p.K76N | Missense Mutation (SNP) | VAF 10/53 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.953); called by muse, mutect2, varscan2
- XYLT1 | c.2024G>C p.C675S | Missense Mutation (SNP) | VAF 10/65 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.832); called by muse, mutect2
- ZNF14 | c.1498_1501del p.E500Nfs*205 | Frame Shift Del (DEL) | VAF 22/184 reads (12%) | called by mutect2, pindel, varscan2
- ABL1 | c.1746C>A p.G582= | Silent (SNP) | VAF 45/182 reads (25%) | catalogued as COSV100583455; called by muse, mutect2, varscan2
- ADCY2 | c.3015T>A p.P1005= | Silent (SNP) | VAF 6/52 reads (12%) | catalogued as COSV100601808; called by muse, mutect2
- ADIG | c.180C>A p.G60= | Silent (SNP) | VAF 6/21 reads (29%) | catalogued as COSV100972521; called by muse, mutect2
- AFDN | c.813A>T p.T271= | Silent (SNP) | VAF 40/170 reads (24%) | catalogued as COSV100652456; called by muse, mutect2, varscan2
- AGBL5 | c.1302T>C p.H434= | Silent (SNP) | VAF 32/286 reads (11%) | catalogued as rs1416313944, COSV100548838; called by muse, mutect2, varscan2
- ALMS1 | c.4155A>G p.T1385= | Silent (SNP) | VAF 67/193 reads (35%) | catalogued as COSV100041145; called by muse, mutect2, varscan2
- ARHGEF15 | c.1578C>T p.D526= | Silent (SNP) | VAF 6/29 reads (21%) | catalogued as rs568213811, COSV100729976; called by muse, varscan2
- ARMH4 | c.2139G>T p.G713= | Silent (SNP) | VAF 14/76 reads (18%) | catalogued as COSV50772874, COSV99957646; called by muse, mutect2, varscan2
- BBOX1 | c.180G>T p.V60= | Silent (SNP) | VAF 14/48 reads (29%) | catalogued as COSV54189761, COSV99589435, COSV99589467; called by muse, mutect2, varscan2
- BCLAF1 | c.411G>A p.R137= | Silent (SNP) | VAF 19/175 reads (11%) | catalogued as rs766469433, COSV100786381; called by muse, mutect2
- BRINP2 | c.2169C>T p.L723= | Silent (SNP) | VAF 25/215 reads (12%) | catalogued as COSV64180924; called by muse, mutect2, varscan2
- C10orf90 | c.996C>T p.G332= | Silent (SNP) | VAF 10/86 reads (12%) | catalogued as rs1393792779, COSV52958280; called by muse, mutect2, varscan2
- C20orf85 | c.405C>A p.G135= | Silent (SNP) | VAF 16/43 reads (37%) | catalogued as rs140824842, COSV100959375; called by muse, mutect2, varscan2
- CC2D2B | c.354T>C p.F118= | Silent (SNP) | VAF 22/49 reads (45%) | catalogued as COSV100729292; called by muse, mutect2, varscan2
- CCDC141 | c.4134C>A p.T1378= | Silent (SNP) | VAF 10/53 reads (19%) | catalogued as COSV99836159; called by muse, mutect2, varscan2
- CCDC80 | c.1095G>A p.T365= | Silent (SNP) | VAF 9/60 reads (15%) | catalogued as rs748668878, COSV99244263; called by muse, mutect2, varscan2
- CDC42BPG | c.945G>T p.L315= | Silent (SNP) | VAF 3/49 reads (6%) | called by muse, mutect2
- CHRM2 | c.168C>G p.T56= | Silent (SNP) | VAF 33/180 reads (18%) | catalogued as rs78847341, COSV100280749, COSV57781043; called by muse, mutect2, varscan2
- CLCN6 | c.9G>A p.G3= | Silent (SNP) | VAF 4/28 reads (14%) | catalogued as rs1216104336, COSV100411581; called by muse, mutect2
- COL4A5 | c.4995G>T p.T1665= | Silent (SNP) | VAF 19/40 reads (48%) | catalogued as COSV100086513; called by muse, mutect2, varscan2
- CPED1 | c.2079A>T p.P693= | Silent (SNP) | VAF 14/96 reads (15%) | catalogued as COSV100119989; called by muse, mutect2, varscan2
- CPZ | c.1800C>A p.P600= (on ENST00000360986 / NM_001014447.3; = p.P589= on NM_003652.3) | Silent (SNP) | VAF 20/51 reads (39%) | catalogued as COSV100248750; called by muse, mutect2, varscan2
- CSMD1 | c.8829C>G p.L2943= (on ENST00000520002; = p.L2942= on NM_033225.6) | Silent (SNP) | VAF 29/111 reads (26%) | catalogued as COSV100143930; called by muse, mutect2, varscan2
- DDX55 | c.753A>T p.A251= | Silent (SNP) | VAF 14/92 reads (15%) | catalogued as COSV99434191; called by muse, mutect2, varscan2
- DENND4A | c.618A>G p.V206= | Silent (SNP) | VAF 19/71 reads (27%) | catalogued as rs747742878, COSV101475261; called by muse, mutect2, varscan2
- DISP2 | c.1080C>T p.D360= | Silent (SNP) | VAF 13/102 reads (13%) | catalogued as rs1222278600, COSV99139695; called by muse, mutect2, varscan2
- DNM1 | c.1719G>T p.R573= | Silent (SNP) | VAF 19/71 reads (27%) | catalogued as COSV100359503; called by muse, mutect2, varscan2
- F13B | c.1125G>A p.E375= | Silent (SNP) | VAF 23/94 reads (24%) | catalogued as rs1160341546, COSV100803188; called by muse, mutect2, varscan2
- FAM171A1 | c.729G>T p.A243= | Silent (SNP) | VAF 13/74 reads (18%) | catalogued as rs773954432, COSV100968019, COSV65313458; called by muse, mutect2, varscan2
- FCRLA | c.312C>A p.I104= (on ENST00000367959; = p.I81= on NM_032738.4) | Silent (SNP) | VAF 32/67 reads (48%) | catalogued as rs142998045; called by muse, mutect2, varscan2
- GALNT13 | c.1032T>A p.V344= | Silent (SNP) | VAF 13/252 reads (5%) | catalogued as COSV101222219; called by muse, mutect2
- GATA3 | c.1065T>A p.T355= | Silent (SNP) | VAF 7/48 reads (15%) | catalogued as COSV60521368; called by muse, mutect2, varscan2
- GP2 | c.489G>T p.V163= | Silent (SNP) | VAF 7/39 reads (18%) | catalogued as COSV100221257; called by muse, mutect2, varscan2
- GPR32 | c.411G>T p.V137= | Silent (SNP) | VAF 15/135 reads (11%) | catalogued as rs775663056, COSV99567073; called by muse, mutect2, varscan2
- HDGFL1 | c.231G>T p.A77= | Silent (SNP) | VAF 12/30 reads (40%) | catalogued as COSV100014478; called by muse, mutect2
- HYDIN | c.10983C>T p.C3661= | Silent (SNP) | VAF 6/62 reads (10%) | catalogued as COSV101152215; called by muse, mutect2, varscan2
- IGF2BP2 | c.1137C>T p.S379= | Silent (SNP) | VAF 13/29 reads (45%) | catalogued as rs751810583, COSV100648846; called by muse, varscan2
- ITGB3 | c.498C>T p.T166= | Silent (SNP) | VAF 45/173 reads (26%) | catalogued as COSV101457537; called by muse, mutect2, varscan2
- KCNT2 | c.409C>A p.R137= | Silent (SNP) | VAF 7/33 reads (21%) | catalogued as COSV99651569; called by muse, mutect2, varscan2
- KIR3DL3 | c.993C>A p.V331= | Silent (SNP) | VAF 47/135 reads (35%) | catalogued as COSV99399710; called by muse, mutect2, varscan2
- MIA2 | c.1836A>G p.Q612= | Silent (SNP) | VAF 9/49 reads (18%) | catalogued as rs146750332; called by muse, mutect2, varscan2
- MOAP1 | c.642A>C p.A214= | Silent (SNP) | VAF 12/171 reads (7%) | catalogued as COSV99365631; called by muse, mutect2
- MRPS17 | c.258C>T p.F86= | Silent (SNP) | VAF 27/210 reads (13%) | catalogued as COSV99567773; called by muse, mutect2, varscan2
- NAT1 | c.843C>A p.P281= | Silent (SNP) | VAF 9/37 reads (24%) | catalogued as COSV100306448; called by muse, mutect2, varscan2
- NAV1 | c.4152C>A p.R1384= | Silent (SNP) | VAF 15/143 reads (10%) | catalogued as COSV99818215; called by muse, mutect2, varscan2
- NAV2 | c.4143G>A p.K1381= (on ENST00000396087 / NM_001244963.2; = p.K1358= on NM_145117.5) | Silent (SNP) | VAF 18/111 reads (16%) | catalogued as COSV100216114; called by muse, mutect2, varscan2
- NEUROD6 | c.837G>A p.L279= | Silent (SNP) | VAF 5/66 reads (8%) | catalogued as COSV99773856; called by muse, mutect2
- NLGN4X | c.879G>T p.P293= | Silent (SNP) | VAF 12/43 reads (28%) | catalogued as COSV99319899; called by muse, mutect2, varscan2
- NLRP11 | c.558C>T p.L186= | Silent (SNP) | VAF 13/44 reads (30%) | catalogued as COSV100789632; called by muse, mutect2, varscan2
- OLFM1 | c.1362C>T p.Y454= (on ENST00000371793 / NM_001282611.2; = p.Y436= on NM_014279.5) | Silent (SNP) | VAF 19/113 reads (17%) | catalogued as COSV99423239; called by muse, mutect2, varscan2
- OLFM4 | c.648C>A p.I216= | Silent (SNP) | VAF 23/88 reads (26%) | catalogued as COSV99524185; called by muse, mutect2, varscan2
- OPTC | c.699C>A p.L233= | Silent (SNP) | VAF 28/120 reads (23%) | catalogued as COSV100921728; called by muse, mutect2, varscan2
- OR10G3 | c.888G>A p.V296= | Silent (SNP) | VAF 12/69 reads (17%) | catalogued as COSV100336060; called by muse, mutect2, varscan2
- OR2L13 | c.208C>T p.L70= | Silent (SNP) | VAF 42/265 reads (16%) | catalogued as rs1353561478, COSV100813667; called by muse, mutect2, varscan2
- OR4C15 | c.414C>T p.S138= (on ENST00000314644; = p.S84= on NM_001001920.2) | Silent (SNP) | VAF 26/206 reads (13%) | catalogued as COSV100115369; called by muse, varscan2
- OR51B4 | c.399T>A p.L133= | Silent (SNP) | VAF 11/135 reads (8%) | catalogued as COSV100970589; called by muse, mutect2
- OR5L2 | c.753C>T p.S251= | Silent (SNP) | VAF 18/100 reads (18%) | catalogued as COSV101004228, COSV101004244; called by muse, mutect2, varscan2
- OR7A17 | c.405C>T p.I135= | Silent (SNP) | VAF 51/97 reads (53%) | catalogued as COSV100541561; called by muse, mutect2, varscan2
- PACS2 | c.186G>T p.V62= | Silent (SNP) | VAF 16/67 reads (24%) | catalogued as COSV100330604; called by muse, mutect2, varscan2
- PBX1 | c.408T>C p.S136= | Silent (SNP) | VAF 6/60 reads (10%) | catalogued as COSV100522042; called by muse, mutect2
- PCDHB10 | c.390G>T p.A130= | Silent (SNP) | VAF 51/113 reads (45%) | catalogued as rs782047686, COSV53382786, COSV99503656; called by muse, mutect2, varscan2
- PCDHB10 | c.1638G>T p.L546= | Silent (SNP) | VAF 13/34 reads (38%) | catalogued as COSV99503659; called by muse, mutect2, varscan2
- PCDHB3 | c.1440A>T p.S480= | Silent (SNP) | VAF 58/282 reads (21%) | catalogued as COSV50584498, COSV99164173; called by muse, mutect2, varscan2
- PCDHB8 | c.2346A>T p.P782= | Silent (SNP) | VAF 40/80 reads (50%) | catalogued as COSV99175638; called by muse, mutect2, varscan2
- PDCL | c.708G>A p.L236= | Silent (SNP) | VAF 25/95 reads (26%) | catalogued as COSV99414065; called by muse, mutect2, varscan2
- PRICKLE2 | c.2178G>T p.R726= (on ENST00000295902; = p.R670= on NM_198859.4) | Silent (SNP) | VAF 4/84 reads (5%) | called by muse, mutect2
- PRUNE2 | c.7548A>G p.E2516= | Silent (SNP) | VAF 52/160 reads (33%) | catalogued as COSV100944226; called by muse, mutect2, varscan2
- RAB3GAP1 | c.1716A>T p.G572= | Silent (SNP) | VAF 18/50 reads (36%) | catalogued as COSV99920615; called by muse, mutect2, varscan2
- RASGRP3 | c.375C>T p.S125= | Silent (SNP) | VAF 29/132 reads (22%) | catalogued as COSV101274690; called by muse, mutect2, varscan2
- RGS11 | c.708G>T p.A236= (on ENST00000397770 / NM_183337.3; = p.A215= on NM_003834.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 17/61 reads (28%) | catalogued as rs944418493, COSV51451613, COSV51452682, COSV99395600; called by muse, mutect2, varscan2
- RPTN | c.2130C>A p.G710= | Silent (SNP) | VAF 204/406 reads (50%) | catalogued as COSV100285251; called by muse, mutect2, varscan2
- RSRP1 | c.186C>T p.S62= | Silent (SNP) | VAF 21/98 reads (21%) | catalogued as COSV99682558; called by muse, mutect2, varscan2
- SEMA6A | c.2736C>T p.Y912= | Silent (SNP) | VAF 37/101 reads (37%) | catalogued as rs376332713; called by muse, mutect2, varscan2
- SLC16A14 | c.429G>T p.L143= | Silent (SNP) | VAF 7/68 reads (10%) | catalogued as COSV99725181; called by muse, mutect2
- SLC26A3 | c.531G>T p.A177= | Silent (SNP) | VAF 17/39 reads (44%) | catalogued as rs543522300, COSV100384820, COSV60639071; called by muse, mutect2, varscan2
- SSUH2 | c.402T>G p.P134= | Silent (SNP) | VAF 29/65 reads (45%) | catalogued as COSV100435581; called by muse, mutect2, varscan2
- STARD6 | c.321C>G p.S107= | Silent (SNP) | VAF 10/62 reads (16%) | catalogued as COSV100323362, COSV57141668; called by muse, mutect2, varscan2
- SUPT7L | c.438G>C p.V146= | Silent (SNP) | VAF 9/50 reads (18%) | catalogued as COSV100536253; called by muse, mutect2, varscan2
- TLL2 | c.906C>A p.A302= | Silent (SNP) | VAF 40/213 reads (19%) | catalogued as COSV63575578; called by muse, mutect2, varscan2
- TMEM117 | c.1350A>T p.R450= | Silent (SNP) | VAF 12/147 reads (8%) | catalogued as COSV56915652, COSV99861829; called by muse, mutect2
- TOR1B | c.672G>T p.T224= | Silent (SNP) | VAF 39/112 reads (35%) | catalogued as COSV99399969; called by muse, mutect2, varscan2
- TRPV5 | c.1251A>G p.G417= | Silent (SNP) | VAF 30/127 reads (24%) | catalogued as COSV99520102; called by muse, mutect2, varscan2
- TUBB8 | c.1119C>T p.A373= | Silent (SNP) | VAF 24/140 reads (17%) | catalogued as COSV100225911; called by muse, mutect2, varscan2
- TULP3 | c.522C>T p.A174= | Silent (SNP) | VAF 40/156 reads (26%) | catalogued as rs200046674, COSV101237473; called by muse, mutect2, varscan2
- UGT1A4 | c.312A>G p.E104= | Silent (SNP) | VAF 108/236 reads (46%) | catalogued as rs373602050; called by muse, mutect2, varscan2
- UNC45A | c.1440G>T p.S480= | Silent (SNP) | VAF 40/74 reads (54%) | catalogued as COSV101265691; called by muse, mutect2, varscan2
- XIRP1 | c.3366G>A p.R1122= | Silent (SNP) | VAF 6/76 reads (8%) | catalogued as rs1159700204, COSV61139489; called by muse, mutect2
- ZFHX4 | c.4044G>A p.Q1348= | Silent (SNP) | VAF 6/26 reads (23%) | catalogued as COSV99256251; called by muse, mutect2
- ZNF292 | c.5466A>G p.K1822= | Silent (SNP) | VAF 19/33 reads (58%) | catalogued as COSV100369768; called by muse, mutect2, varscan2
- ZPBP | c.603G>T p.L201= | Silent (SNP) | VAF 24/116 reads (21%) | catalogued as rs368068090; called by muse, mutect2, varscan2
- ABCC5 | c.591+2361A>T | Intron (SNP) | VAF 50/107 reads (47%) | catalogued as COSV99656406; called by muse, mutect2, varscan2
- AC244258.1 | n.344C>T | RNA (SNP) | VAF 22/128 reads (17%) | called by muse, mutect2, varscan2
- ARPP19P2 | n.21G>T | RNA (SNP) | VAF 9/37 reads (24%) | called by muse, mutect2, varscan2
- C14orf177 | n.542C>G | RNA (SNP) | VAF 8/47 reads (17%) | catalogued as COSV100362604; called by muse, mutect2, varscan2
- CLCN5 | c.17-29008G>T | Intron (SNP) | VAF 21/150 reads (14%) | catalogued as COSV101066939; called by muse, mutect2, varscan2
- PKD1L1 | c.6966-2714A>T | Intron (SNP) | VAF 4/51 reads (8%) | catalogued as COSV99218443; called by muse, mutect2
- RGS8 | c.-127G>T | 5'UTR (SNP) | VAF 31/95 reads (33%) | catalogued as COSV99276436; called by muse, mutect2, varscan2
- RIPOR3 | chr20:50585836 G>C | 3'Flank (SNP) | VAF 4/46 reads (9%) | called by muse, mutect2
- SNORD115-40 | n.30T>G | RNA (SNP) | VAF 55/349 reads (16%) | called by muse, mutect2, varscan2
- TOR1AIP2 | c.-146-12030A>G | Intron (SNP) | VAF 38/185 reads (21%) | catalogued as COSV100857284; called by muse, mutect2, varscan2
- USP32 | c.1239+4580C>T | Intron (SNP) | VAF 37/92 reads (40%) | catalogued as COSV56264870; called by muse, mutect2, varscan2
